Somatic mutation profile of tumor specimen ALCH-B0G1-TTP1-A (aliquot ALCH-B0G1-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0G1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 44.4 years (16,226 days).
Specimen ALCH-B0G1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 042553fb-499b-471b-93cb-867d7b5c58f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0G1-NB1-A (Blood Derived Normal), aliquot ALCH-B0G1-NB1-A-5-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18977461-3399-4df6-b050-82a46c1e0661

The open-access MAF lists 54 somatic variants for this specimen: 34 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 17, Nonsense Mutation 2, 5'UTR 2, In Frame Ins 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 21/433 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs121917918, CM044039, COSV100320807; ClinVar: pathogenic; called by muse, mutect2
- ADCK5 | c.91A>G p.R31G | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.287); catalogued as rs782287690; called by muse, mutect2
- ADGRV1 | c.3142A>G p.R1048G | Missense Mutation (SNP) | VAF 81/474 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV67993676; called by muse, mutect2, varscan2
- AMN | c.663G>C p.W221C | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as CM124403; called by muse, mutect2, varscan2
- CDC14B | c.1319C>A p.S440Y | Missense Mutation (SNP) | VAF 39/338 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV55787898; called by muse, mutect2, varscan2
- MAP2 | c.2581G>A p.D861N | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99562219; called by muse, mutect2
- MYH14 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs1247968157; called by muse, mutect2, varscan2
- PIK3CA | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs397517199, COSV104381248, COSV55880235, COSV55880477; ClinVar: uncertain significance; called by muse, mutect2
- PLCL1 | c.2065G>T p.G689W | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70830591; called by muse, mutect2
- STRN3 | c.1429C>T p.R477C (on ENST00000357479 / NM_001083893.2; = p.R393C on NM_014574.4) | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1482165566; called by muse, mutect2
- ABCB7 | c.1497G>C p.K499N (on ENST00000373394 / NM_001271696.3; = p.K500N on NM_004299.6) | Missense Mutation (SNP) | VAF 44/844 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); called by muse, mutect2
- ADH1C | c.889C>G p.P297A | Missense Mutation (SNP) | VAF 93/590 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- AMMECR1L | c.722A>G p.Q241R | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2
- ARHGAP40 | c.1757A>T p.Y586F | Missense Mutation (SNP) | VAF 125/550 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- C2orf69 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2
- CHD7 | c.8095A>T p.M2699L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.558); called by muse, mutect2
- CNKSR2 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 66/383 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- EFHC2 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 9/225 reads (4%) | called by muse, mutect2
- GNPNAT1 | c.123G>C p.L41F | Missense Mutation (SNP) | VAF 34/321 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- KCNJ2 | c.580G>C p.V194L | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- LYPLA2 | c.524T>C p.L175P | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.251); called by muse, mutect2
- MBD5 | c.3332C>T p.T1111I | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.398); called by muse, mutect2
- MBTPS2 | c.438G>C p.V146= | Splice Region (SNP) | VAF 26/313 reads (8%) | called by muse, mutect2
- MYD88 | c.449T>G p.L150R | Missense Mutation (SNP) | VAF 56/363 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPM2 | c.447G>C p.E149D | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.011); called by muse, mutect2
- OR4D2 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 151/1047 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by mutect2, varscan2
- OR52D1 | c.369T>G p.F123L | Missense Mutation (SNP) | VAF 32/597 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.687); called by muse, mutect2
- PARP8 | c.1963C>A p.L655M | Missense Mutation (SNP) | VAF 10/310 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- PRSS41 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- SETD2 | c.1100C>G p.S367* | Nonsense Mutation (SNP) | VAF 77/280 reads (28%) | called by muse, mutect2, varscan2
- UGGT2 | c.3196_3198dup p.N1066dup | In Frame Ins (INS) | VAF 16/116 reads (14%) | called by mutect2, pindel
- ZIC5 | c.1976T>A p.V659E | Missense Mutation (SNP) | VAF 72/337 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF727 | c.344A>G p.K115R | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2
- ZP3 | c.182G>A p.G61D (on ENST00000394857 / NM_001110354.2; = p.G10D on NM_007155.6) | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2
- ABCB7 | c.1098T>A p.A366= (on ENST00000373394 / NM_001271696.3; = p.A367= on NM_004299.6) | Silent (SNP) | VAF 21/350 reads (6%) | called by muse, mutect2
- AHRR | c.1869C>T p.D623= | Silent (SNP) | VAF 47/187 reads (25%) | catalogued as rs539730239, COSV57094822; called by muse, mutect2, varscan2
- CERS2 | c.1026C>T p.D342= | Silent (SNP) | VAF 17/294 reads (6%) | called by muse, mutect2
- CYP1B1 | c.495C>A p.V165= | Silent (SNP) | VAF 9/227 reads (4%) | called by muse, mutect2
- FCRLA | c.984C>A p.G328= (on ENST00000367959; = p.G305= on NM_032738.4) | Silent (SNP) | VAF 24/546 reads (4%) | called by muse, mutect2
- FLT4 | c.237G>T p.G79= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs1424021649, COSV56101637; called by muse, mutect2, varscan2
- HSD3B2 | c.60C>T p.R20= | Silent (SNP) | VAF 26/492 reads (5%) | catalogued as COSV101027427; called by muse, mutect2
- KMT2B | c.402C>T p.P134= | Silent (SNP) | VAF 56/251 reads (22%) | catalogued as rs1290736989; called by muse, mutect2, varscan2
- LSM2 | c.270C>G p.A90= | Silent (SNP) | VAF 12/322 reads (4%) | called by muse, mutect2
- MUC16 | c.8937T>C p.T2979= | Silent (SNP) | VAF 14/264 reads (5%) | catalogued as COSV67461394; called by muse, mutect2
- PKHD1L1 | c.9021C>T p.L3007= | Silent (SNP) | VAF 18/432 reads (4%) | called by muse, mutect2
- RELN | c.4440C>A p.G1480= | Silent (SNP) | VAF 74/627 reads (12%) | catalogued as COSV100635430; called by muse, mutect2, varscan2
- SLC6A14 | c.987C>A p.G329= | Silent (SNP) | VAF 88/488 reads (18%) | called by muse, mutect2, varscan2
- SLC6A9 | c.2055G>A p.P685= (on ENST00000360584 / NM_201649.4; = p.P631= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/299 reads (7%) | catalogued as rs750360264; called by muse, mutect2
- SLC9A2 | c.849C>T p.I283= | Silent (SNP) | VAF 32/632 reads (5%) | catalogued as rs771641119; called by muse, mutect2
- TCF20 | c.5841C>T p.T1947= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as rs201866155, COSV100166434; called by muse, mutect2
- ZNF354A | c.198G>A p.L66= | Silent (SNP) | VAF 31/490 reads (6%) | called by muse, mutect2
- CRK | c.-47G>A | 5'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as rs937553464; called by mutect2, varscan2
- METTL22 | c.*226_*227del | 3'UTR (DEL) | VAF 72/392 reads (18%) | called by pindel, varscan2
- NRBF2 | c.-90C>T | 5'UTR (SNP) | VAF 29/108 reads (27%) | catalogued as COSV99515189; called by muse, mutect2, varscan2
